Gene-level copy-number profile of tumor specimen TCGA-VQ-A8PM-01A from TCGA case TCGA-VQ-A8PM, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.6 years (20,665 days).
Specimen TCGA-VQ-A8PM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.3a6624e7-f1bd-4949-bf53-5be4aff02615.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8PM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c01efd30-a6f1-4ffc-acea-4f07ab2b12f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 16,895; copy number 2: 37,869; copy number 3: 3,654; copy number 4: 818; copy number 5: 231; copy number 6: 229; copy number 8: 70; copy number 9: 1; copy number 12: 16; copy number 22: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8PM-01A-21D-A40Z-01): tumor purity 0.3, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,741,581–58,863,414, 3 genes: AC016642.1, RPL5P15, AC008852.1.
- chr5:59,039,761–59,529,251, 3 genes: AC092343.1, AC008833.1, NDUFB4P2.
- chr10:75,431,624–76,560,168, 1 gene (within-gene range 0–2): LRMDA.
- chr10:75,552,458–76,438,775, 8 genes: MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 558 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,576,605–168,729,206, 2 genes, copy number 5 (within-gene range 4–5): XCL1, DPT.
- chr19:29,489,775–30,713,538, 23 genes, copy number 5–22: AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1.
- chr20:38,127,385–39,233,836, 42 genes, copy number 8 (within-gene range 2–8): TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19, LINC01734, AL035251.1.
- chr20:43,914,852–46,171,237, 106 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:46,859,333–63,744,050, 384 genes, copy number 5–12 (broad region; genes not listed).
- chr20:63,744,689–63,745,958, 1 gene, copy number 6: AL121845.1.

Autosomal genes at a single copy (total copy number 1): 14,516. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
